Somatic mutation profile of tumor specimen TCGA-V4-A9EK-01A (aliquot TCGA-V4-A9EK-01A-11D-A39W-08) from TCGA case TCGA-V4-A9EK, project TCGA-UVM (Uveal Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Spindle cell melanoma, NOS; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIB; Age at diagnosis: 37.6 years (13,731 days).
Specimen TCGA-V4-A9EK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5b0ce215-9483-4c9c-ba8f-c61c64a5a8ce.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V4-A9EK-10A (Blood Derived Normal), aliquot TCGA-V4-A9EK-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/49ab2d48-2910-46cb-88aa-647ade699777

The open-access MAF lists 13 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 2, Frame Shift Del 1, Nonstop Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAQ | c.626A>C p.Q209P | Missense Mutation (SNP) | VAF 20/50 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121913492, COSV54105903, COSV54105914, COSV54108414; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AADACL4 | c.334C>T p.R112W | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.317); catalogued as rs559695381; called by muse, mutect2, varscan2
- PNLIP | c.620G>A p.R207Q | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs149884015, COSV65041649; called by muse, mutect2, varscan2
- SPHKAP | c.4015G>A p.G1339S | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.03); catalogued as rs1338854193; called by muse, mutect2, varscan2
- ABCA13 | c.2624A>T p.Q875L | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- COL14A1 | c.1838A>G p.E613G | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- DNM1 | c.1774G>A p.E592K | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); called by muse, varscan2
- PCLO | c.5065del p.T1689Qfs*16 | Frame Shift Del (DEL) | VAF 4/13 reads (31%) | called by mutect2, varscan2
- RGS20 | c.1166A>G p.*389Wext*20 (on ENST00000297313 / NM_170587.4; = p.*242Wext*20 on NM_003702.4) | Nonstop Mutation (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2
- USP34 | c.8990T>C p.L2997P | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- DNM1 | c.1683G>A p.K561= | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as rs1263582663, COSV57854389; called by muse, varscan2
- FTHL17 | c.237C>A p.G79= | Silent (SNP) | VAF 8/49 reads (16%) | called by muse, mutect2, varscan2
- AGAP7P | n.1511G>T | RNA (SNP) | VAF 28/240 reads (12%) | catalogued as rs1554941383; called by muse, mutect2
